Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2PM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2PM-01A (Primary Tumor).

[page 1 of 2]
RUN DATE: ()
RUN TIME: ()
BY: ()

PATIENT: () ACCT #: () LOC: () U#: ()
REG DR: () AGE/SX: () RM/BED: () REG: ()
STATUS: () TLOC: () DIS: ()

SPEC #: PN: () Obtained: () Subm Dr: ()
STATUS: () Received: ()
CLINICAL HISTORY: ()
R/O CANCER ()
SPECIMEN/PROCEDURE: ()
1. CERVIX - BIOPSY; ()
2. CERVIX - BIOPSY ()

ICD-0-3
carcinoma, squamous cell, large cell,
keratinizing 8071/3
Site: Cervix, NOS C53.9 8/23/11
h

IMPRESSION:

- 1) CERVIX, BIOPSY:
. Invasive squamous cell carcinoma, large cell keratinizing type, poorly differentiated.
- 2) CERVIX, BIOPSY:
. Invasive squamous cell carcinoma, large cell keratinizing type, poorly differentiated.

Dictated: ()
Entered: ()

COMMENT:

Case reviewed at the ()
Entered: ()

SPECIAL STAINS/PROCEDURES:

One initial frozen section (1F).

Dictated by: ()

GROSS DESCRIPTION:

- 1) Received fresh in a container with the patient's name, medical record number and "cervical biopsy", is a 1.8 x 1 x 0.3 cm tan pink hemorrhage tissue. Entirely submitted for frozen section.

FROZEN SECTION DIAGNOSIS: Invasive squamous cell carcinoma. Results called to Dr. ()

CONTINUED ON NEXT PAGE **

[page 2 of 2]
GROSS DESCRIPTION: (continued)

- 2) received in formalin, labeled "cervical biopsy at _____ and with the patient's name, is an aggregate of irregular portions of pink-tan to red-tan glistening tissue admixed with deep red blood clot, 2.5 x 2.0 x 0.5 cm. The specimen is filtered and entirely submitted in two cassettes.

Dictated

Entered:

COPIES TO:

CPT Codes:

FS :

CERVICAL BIOPSY (

ICD9 Codes:

Electronically Signed by: _____

** END OF REPORT **

Source: NCI Genomic Data Commons file 72253416-d880-48cc-acc0-0a480afe31d2 (TCGA-EK-A2PM.B1AB121F-E75E-4AE1-9C9A-16076A3B7879.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).